Somatic mutation profile of tumor specimen BA2642D (aliquot aq-BA2642D) from BEATAML1.0 case 2072, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.9 years (30,630 days).
Specimen BA2642D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e7812a9-7760-4441-bbb5-a447bb78bb71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2571D (Solid Tissue Normal), aliquot aq-BA2571D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c87e3ae1-6eba-48c8-b448-950ddcc5ea50

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAP1L1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV53873658; called by muse, mutect2, varscan2
- OPHN1 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs953339084, COSV62788442; called by muse, mutect2
- POTEJ | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs776474594; called by muse, varscan2
- CFAP99 | c.643-3C>A | Splice Region (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- GTDC1 | c.1168C>T p.P390S (on ENST00000344850 / NM_001354361.1; = p.P305S on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2
- RBM20 | c.1874C>A p.A625E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.444); called by muse, mutect2
- CCDC170 | c.1590C>T p.N530= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as rs375623063; called by muse, mutect2, varscan2
- KRT75 | c.549C>T p.L183= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- LRP2 | c.11133G>A p.E3711= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
